Somatic mutation profile of tumor specimen MP2PRT-PAVEEC-TMP1-A (aliquot MP2PRT-PAVEEC-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVEEC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (820 days).
Specimen MP2PRT-PAVEEC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 147db2b1-e6ce-4864-8531-5ad061e1583b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVEEC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVEEC-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71911887-2893-4785-a523-3858d1a954b8

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 60/335 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 86/310 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs121918461, CM013415, CM098208, COSV61004983, COSV61005256, COSV61011211; ClinVar: pathogenic; called by muse, mutect2, varscan2
- INAVA | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 58/636 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs766204092; called by muse, mutect2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 82/428 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF507 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 68/280 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as rs745604662; called by muse, mutect2, varscan2
- DYNC2H1 | c.9077T>A p.I3026N | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- NLGN4Y | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 220/556 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ACE2 | c.1062C>T p.G354= | Silent (SNP) | VAF 119/318 reads (37%) | catalogued as rs200909433; called by muse, mutect2, varscan2
- CACNA1H | c.4812G>A p.S1604= | Silent (SNP) | VAF 43/562 reads (8%) | catalogued as rs377611664; called by muse, mutect2
- KCND2 | c.480C>T p.S160= | Silent (SNP) | VAF 151/522 reads (29%) | catalogued as rs761095237, COSV58581400; called by muse, mutect2, varscan2
